Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA51, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA51-01A (Primary Tumor).

Histopathology Histopathology

Specimen Comments

SPECIMEN

Bladder tumour

CLINICAL DETAILS

New TCC bladder. Solid looking. ?Muscle invasion. TURT done.

MACROSCOPY

7g of firm and friable tissue chippings.

MICROSCOPY

Grade 3 Poorly differentiated

Growth pattern Mixed papillary and solid

Type Transitional cell carcinoma

Muscularis propria present Yes

Stromal invasion Invasion of muscularis propria

Vascular channel invasion Not identified

Background urothelium No flat urothelium is identified

Summary Transitional cell carcinoma G3pT2

Ref:

Pathologists -

HLF ICD-O-3
path Carcinoma, urothelial NOS 8120/3
path Carcinoma, transitional cell NOS 8120/3
Site: Bladder NOS C67.9
W 4/30/14

Source: NCI Genomic Data Commons file 981b00cb-f1dc-4411-b10c-09118b2f69a3 (TCGA-ZF-AA51.F2059BDD-0218-47A9-BBA8-BFE95D1CD55E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).